Surgical pathology report (de-identified scan), TCGA case TCGA-29-1763, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1763-01A (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Pelvic mass.

GROSS EXAMINATION:

A. "Right fallopian tube and ovary", received fresh for frozen section is a partially disrupted 10 x 3 x 3 cm, 337 gram ovary. The serosa demonstrates numerous fibrinous adhesions. The opened ovary is covered with tan-yellow papillary tumor. There is no normal ovarian architecture identified. Attached to the ovary is an 8.0 cm long fallopian tube with an average diameter of 0.5 cm. The fallopian tube does not grossly appear to be involved by tumor. Representative sections are submitted as follows:

BLOCK SUMMARY:

A1- frozen section remnant.

A2- fallopian tube.

A3-A4- representative sections of tumor and overlying serosa.

A5-A6- representative sections of fibrillary tumor projecting into lumen of ovary.

B. "Left fallopian tube and ovary". Received in formalin is a 52.4 gram, specimen consists of a 4.0 x 3.0 x 2.5 cm ovary with an attached 6.0 cm long fallopian tube with an average diameter of 0.5 cm. Contiguous with the ovary is a multiloculated cyst. The cyst wall thickness varies from 0.1 cm to 0.5 cm and lacks papillary excrescences. The cut surface of the ovary is tan-white, whorled fibrous tissue.

BLOCK SUMMARY:

B1- ovary.

B2- thick wall of multiloculated cyst and additional cyst wall.

B3- fallopian tube.

B4- additional sections of ovary.

C. "Uterus and cervix". Received in formalin that is a 109.5 gram, 10.5 x 6.5 x 4.0 cm uterus with a 3.0 cm cervix that demonstrates a 0.6 cm cervical os. The uterus is opened longitudinally and demonstrates a 4.0 cm in diameter intramural whorled nodule grossly consistent with leiomyoma. There are two additional nodules consistent with leiomyomata projecting from the fundus (1.5 cm and 2.0 cm in diameter). The myometrium has a uniform thickness of 2.0 cm. The endometrium is 0.2 cm thick. The trabeculated endocervical canal and smooth, pink ectocervix demonstrates no gross abnormalities. The serosa is smooth, tan-pink and glistening.

BLOCK SUMMARY:

C1- anterior endocervix.

C2- posterior endocervix.

C3- largest leiomyoma.

C4- anterior endomyometrium.

C5- posterior endomyometrium.

D. "Left pelvic side wall". Received in formalin is a 5.0 x 4.0 x 0.2 cm specimen of fibroadipose tissue entirely submitted in block D1.

E. "Posterior cul de sac". Received in formalin is a 5.0 x 4.0 x 0.5 cm specimen of fibroadipose tissue that demonstrates a 1.0 cm tan nodule. The tissue is sectioned and entirely submitted in blocks E1-E2.

[page 2 of 3]
TCGA-29-1763

F. "Omentum". Received in formalin are multiple sections of omentum with an aggregate measurement of 15.0 x 14.0 x 0.4 cm. There are no focal lesions, masses or abnormalities. Representative sections submitted in block F1.

INTRA OPERATIVE CONSULTATION:

A. "Right fallopian tube and ovary": AFI- carcinoma consistent with serous carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

IMMUNOHISTOCHEMICAL FINDINGS:

Sections from the paraffin block are cut at 4-5 micrometers, placed on positively-charged glass slides, deparaffinized in organic solvents, treated with methanolic H2O2 to quench endogenous peroxidase activity, and rehydrated. Sections are treated with primary antibodies to detect the antigen(s) in question, or with non-immune rabbit immunoglobulin(s) or mouse isotype(s) as a negative control; appropriate positive tissue controls are also tested. Sections are sequentially reacted with biotinylated secondary antibody and with streptavidin or avidin-biotin-complex labeled with horseradish peroxidase. Immunoreactivity is visualized using diaminobenzidine as the chromogen. Counterstaining is performed. The results are as follows:

Tumor cells in the left and right ovary have the following immunoprofile:

CA-125, EMA - positive
Calretinin, inhibin - negative.

DIAGNOSIS:

A. "RIGHT OVARY AND FALLOPIAN TUBE" (SALPINGO-OOPHORECTOMY):

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 2 (MODERATELY DIFFERENTIATED)
TUMOR SIZE: 10 X 3 X 3 CM.
WEIGHT: 337 GRAMS
SEROSA: UNINVOLVED.
PATH STAGING: 2B FIGO. SEE NOTE.
FALLOPIAN TUBE, NO PATHOLOGIC DIAGNOSIS.

NOTE: Information on pathology staging and the operative procedure is being transmitted to this [REDACTED] as required for accreditation purposes by the [REDACTED]. Pathology staging is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Anatomic pathology staging is only a component to be considered in determining the clinical stage, but should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

B. "LEFT OVARY AND FALLOPIAN TUBE" (SALPINGO-OOPHORECTOMY):

OVARY WITH SEROUS CARCINOMA, 1.6 CM IN GREATEST DIMENSION AND LEIOMYOMA
FALLOPIAN TUBE WITH PREDOMINANTLY MUCOSAL CHANGES OF SEROUS CARCINOMA.

C. "UTERUS" (HYSTERECTOMY):

ENDOMETRIUM: PROLIFERATIVE.
MYOMETRIUM: LEIOMYOMATA.
CERVIX: NO PATHOLOGIC DIAGNOSIS.
SEROSA: NO PATHOLOGIC DIAGNOSIS.

D. "LEFT PELVIC SIDEWALL" (BIOPSY):

[page 3 of 3]
TCGA-29-1763

FIBROCONNECTIVE TISSUE, NO TUMOR PRESENT.

E. "POSTERIOR CUL SE SAC" (BIOPSY):

SEROUS CARCINOMA PRESENT. SEE NOTE.

NOTE: There is marked squamous differentiation.

F. "OMENTUM" (OMENECTOMY):

ADIPOSE TISSUE, NO TUMOR PRESENT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

COMMENT:

This case has been discussed with

[REDACTED]

Source: NCI Genomic Data Commons file b680283c-c317-41e2-80a5-788f1fd08804 (TCGA-29-1763.F90E0DB8-F656-411C-BE72-8E0774D2336B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).